Somatic mutation profile of tumor specimen HCM-BROD-0254-C49-86M (aliquot HCM-BROD-0254-C49-86M-01D-A85C-36) from HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95ec0ecd-ea46-495d-9b2b-edee1afb134e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0254-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0254-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e64a79b-dc4e-4bdf-aa3e-3c9d206048d3

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 19, Nonsense Mutation 3, Frame Shift Ins 3, Intron 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs74315293, CM920217, COSV53760198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD18B | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 97/660 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1338234688; called by muse, mutect2, varscan2
- CCDC168 | c.14248G>A p.E4750K | Missense Mutation (SNP) | VAF 173/366 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV104400384; called by muse, mutect2
- CDC42SE1 | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 85/637 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.765); catalogued as COSV61785509; called by muse, mutect2, varscan2
- CDHR4 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs989910867; called by muse, mutect2, varscan2
- CLCN1 | c.1895C>A p.T632N | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV100578275; called by muse, mutect2, varscan2
- CYP11B1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs544670837, COSV52824806, COSV52825753; called by muse, mutect2, varscan2
- DGKD | c.2479G>A p.G827R (on ENST00000264057 / NM_152879.3; = p.G783R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374982750, COSV51095884; called by muse, mutect2, varscan2
- DNAH8 | c.9098G>A p.R3033Q | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370474987; called by muse, mutect2, varscan2
- GFPT2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 120/688 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs537515231; called by muse, mutect2, varscan2
- NOTCH4 | c.4907C>T p.T1636I | Missense Mutation (SNP) | VAF 266/777 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66682790; called by muse, mutect2, varscan2
- OR12D3 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 146/488 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV101011422; called by muse, mutect2, varscan2
- PIK3R2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 184/487 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs773024898, COSV53226279; called by muse, mutect2, varscan2
- RHEX | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 200/452 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.367); catalogued as COSV58982138; called by muse, mutect2, varscan2
- ROCK2 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59963713; called by mutect2, varscan2
- SALL3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 213/660 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs1197931609; called by muse, mutect2, varscan2
- TMEM63B | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 141/479 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52482334; called by muse, mutect2, varscan2
- ABCA10 | c.3752T>C p.M1251T | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADH4 | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 180/380 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP36 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 176/387 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGDIA | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 150/686 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF12 | c.2190-1G>A p.X730_splice | Splice Site (SNP) | VAF 74/443 reads (17%) | called by muse, mutect2, varscan2
- BID | c.421G>C p.D141H (on ENST00000317361 / NM_197966.2; = p.D95H on NM_001196.4) | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK2G | c.1276C>T p.R426* (on ENST00000423381 / NM_001367518.1; = p.R363* on NM_001222.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 144/481 reads (30%) | called by muse, mutect2, varscan2
- CD6 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CWF19L2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 82/442 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DCAF4L1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 107/473 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNMT3B | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 108/647 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERBB2 | c.1784T>G p.F595C | Missense Mutation (SNP) | VAF 58/720 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.33); called by muse, mutect2
- FAM13B | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ITPR3 | c.5362_5364delinsTT p.V1788Ffs*6 | Frame Shift Del (DEL) | VAF 138/522 reads (26%) | called by pindel, varscan2*
- KANK3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 178/628 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- KANSL1 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 140/724 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by mutect2, varscan2
- KLHL3 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 106/526 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- LAMB4 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 138/479 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LYST | c.5654G>C p.C1885S | Missense Mutation (SNP) | VAF 53/568 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- MAGEC1 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MAPRE3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 108/443 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MRPS31 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7A | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 128/765 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OBSCN | c.2485C>A p.H829N | Missense Mutation (SNP) | VAF 124/1154 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ODF2 | c.1366G>T p.G456* (on ENST00000434106 / NM_153433.2; = p.G432* on NM_002540.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/379 reads (21%) | called by muse, mutect2, varscan2
- ODF2 | c.1367G>C p.G456A (on ENST00000434106 / NM_153433.2; = p.G432A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR2L3 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 98/788 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4A8 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 93/492 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCBP3 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PER3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG4 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 133/396 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PTK6 | c.681_682dup p.H228Rfs*13 | Frame Shift Ins (INS) | VAF 101/628 reads (16%) | called by mutect2, pindel, varscan2
- RBM14 | c.1254_1255insCA p.A419Qfs*54 | Frame Shift Ins (INS) | VAF 118/792 reads (15%) | called by mutect2, pindel, varscan2
- RMND5A | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCARF2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 192/617 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, varscan2
- SERPINB4 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SH3RF3 | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 30/916 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- SLC10A7 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC25A43 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SLC45A2 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 674/674 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLCO2B1 | c.150dup p.F51Vfs*100 | Frame Shift Ins (INS) | VAF 76/460 reads (17%) | called by mutect2, pindel, varscan2
- TLN1 | c.6754G>T p.D2252Y | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TMCC2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 89/677 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNRC6C | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 82/513 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TRIM49 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 78/491 reads (16%) | called by muse, mutect2, varscan2
- UMPS | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ALDH1A1 | c.564C>T p.N188= | Silent (SNP) | VAF 57/303 reads (19%) | called by muse, mutect2, varscan2
- B3GNT7 | c.999C>T p.C333= | Silent (SNP) | VAF 141/962 reads (15%) | called by muse, mutect2, varscan2
- BCOR | c.3867C>T p.G1289= (on ENST00000378444 / NM_001123385.2; = p.G1255= on NM_017745.6) | Silent (SNP) | VAF 83/167 reads (50%) | called by muse, mutect2, varscan2
- BID | c.420G>A p.G140= (on ENST00000317361 / NM_197966.2; = p.G94= on NM_001196.4) | Silent (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- BIRC6 | c.8304C>A p.G2768= | Silent (SNP) | VAF 73/396 reads (18%) | catalogued as rs766845760; called by muse, mutect2, varscan2
- CATSPERG | c.2601G>A p.G867= | Silent (SNP) | VAF 91/297 reads (31%) | catalogued as COSV53051110; called by muse, mutect2, varscan2
- CBX6 | c.1053C>T p.S351= | Silent (SNP) | VAF 344/516 reads (67%) | catalogued as rs775494009, COSV99328049; called by muse, mutect2, varscan2
- FNBP4 | c.1050G>A p.E350= | Silent (SNP) | VAF 92/642 reads (14%) | called by muse, mutect2, varscan2
- KIRREL3 | c.456C>T p.I152= | Silent (SNP) | VAF 100/540 reads (19%) | catalogued as rs990996675; called by muse, mutect2, varscan2
- LIMCH1 | c.1788C>A p.A596= | Silent (SNP) | VAF 115/435 reads (26%) | called by muse, mutect2, varscan2
- LPIN2 | c.1452A>G p.S484= | Silent (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- MGAM | c.5490G>A p.T1830= | Silent (SNP) | VAF 78/307 reads (25%) | catalogued as rs752684574, COSV72073855; called by muse, mutect2, varscan2
- OR2L2 | c.888G>T p.V296= | Silent (SNP) | VAF 53/609 reads (9%) | called by muse, mutect2
- PIK3AP1 | c.219G>A p.A73= | Silent (SNP) | VAF 150/676 reads (22%) | catalogued as rs773426752; called by muse, mutect2, varscan2
- SCT | c.6C>A p.A2= | Silent (SNP) | VAF 94/300 reads (31%) | called by mutect2, varscan2
- SLC15A4 | c.378C>T p.P126= | Silent (SNP) | VAF 204/633 reads (32%) | catalogued as rs1242161004; called by muse, mutect2, varscan2
- STAB1 | c.1182G>C p.A394= | Silent (SNP) | VAF 134/463 reads (29%) | called by muse, mutect2, varscan2
- THSD7A | c.507G>A p.A169= | Silent (SNP) | VAF 111/417 reads (27%) | catalogued as rs867019373, COSV101448676; called by muse, mutect2, varscan2
- ZAR1L | c.273G>T p.V91= | Silent (SNP) | VAF 98/1119 reads (9%) | called by muse, mutect2
- KCNQ1 | c.1514+26091C>G | Intron (SNP) | VAF 155/735 reads (21%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5462C>T | Intron (SNP) | VAF 172/733 reads (23%) | catalogued as rs1056453515; called by muse, varscan2
